TCGA case TCGA-HV-A5A3 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: National Cancer Center Korea. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d4f66f06-9289-45c1-b9eb-aaef991a4bb6

Demographics
Sex at birth: male; Race: asian; Country of residence at enrollment: South Korea; Age at index: 50 years; Vital status: Dead; Days to death: 128 days; Cause of death source: Medical Record.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.1; Tissue or organ of origin: Body of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 50.6 years (18,475 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Pancreas Body; Tumor grade category: Three Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 5; Lymph nodes tested: 25.
   Treatment given: Treatment type: Distal Pancreatectomy.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 128 days; Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking quit year: 2002.
- Alcohol history: Yes; Alcohol intensity: Occasional Drinker.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HV-A5A3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 20 mg.
  Slide TCGA-HV-A5A3-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 65; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HV-A5A3-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HV-A5A3-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-HV-A5A3-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 30 mg.
  Slide TCGA-HV-A5A3-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
- Sample TCGA-HV-A5A3-11Z: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Tumor status: Tumor free; Diabetes diagnosis indicator: No; History chronic pancreatitis: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 128 days; disease-specific survival: no event (censored), 128 days; disease-free interval: no event (censored), 128 days; progression-free interval: no event (censored), 128 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HV-A5A3-01A-11D-A26H-01): tumor purity 0.62, ploidy 2.04, whole-genome doublings 0.
